Somatic mutation profile of tumor specimen MP2PRT-PASKXZ-TMP1-A (aliquot MP2PRT-PASKXZ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASKXZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,201 days).
Specimen MP2PRT-PASKXZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e54de4bb-a3c1-43df-8dd6-8fb51ff16041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKXZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKXZ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e40aae-c1ea-49ac-9615-30a4a6b25ad2

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Splice Site 2, In Frame Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 34/319 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2
- ACE | c.3690C>T p.S1230= | Splice Region (SNP) | VAF 32/380 reads (8%) | catalogued as rs778419134, COSV99326428; called by muse, mutect2
- AGBL1 | c.2972G>T p.G991V | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222344; called by muse, mutect2, varscan2
- CACNA1H | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs759273300; called by muse, mutect2, varscan2
- CYP2D6 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 233/622 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs267608276, COSV62243380; called by muse, mutect2, varscan2
- DCDC1 | c.4759C>T p.R1587W (on ENST00000597505 / NM_001367979.1; = p.R694W on NM_020869.3) | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748677084, COSV100360747; called by muse, mutect2, varscan2
- FLCN | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs772207015; called by muse, mutect2
- OSBPL1A | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 17/333 reads (5%) | catalogued as rs371330251; called by muse, mutect2
- PCDH11X | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs753981444, COSV53500777; called by muse, varscan2
- PLG | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 99/559 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs371746732, COSV51981567; called by muse, mutect2, varscan2
- PUM2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 55/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264948684, COSV57585217; called by muse, mutect2, varscan2
- SALL3 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.726); catalogued as rs890658695; called by muse, mutect2, varscan2
- SLC26A4 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749479853, COSV55914647; called by muse, mutect2, varscan2
- ZBED1 | c.1514T>C p.L505P | Missense Mutation (SNP) | VAF 103/990 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs1188610442; called by muse, mutect2, varscan2
- CEP43 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 87/476 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- FCER1G | c.197_198+4del p.X66_splice | Splice Site (DEL) | VAF 57/324 reads (18%) | called by mutect2, pindel, varscan2
- OTOGL | c.5408-1G>A p.X1803_splice (on ENST00000547103; = p.X1794_splice on NM_173591.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 24/150 reads (16%) | called by muse, varscan2
- RAB3B | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TOP2B | c.3320C>T p.P1107L (on ENST00000264331 / NM_001330700.2; = p.P1102L on NM_001068.3) | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZMIZ1 | c.882_883insACCCCC p.T294_A295insTP | In Frame Ins (INS) | VAF 88/610 reads (14%) | called by mutect2, pindel*, varscan2
- ABCA6 | c.4110G>A p.T1370= | Silent (SNP) | VAF 138/570 reads (24%) | catalogued as rs749750215; called by muse, mutect2, varscan2
- MCC | c.969C>T p.I323= | Silent (SNP) | VAF 48/238 reads (20%) | catalogued as rs763704088, COSV100202602, COSV56731752; called by muse, mutect2, varscan2
- MDN1 | c.9220T>C p.L3074= | Silent (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
